Gene-level copy-number profile of tumor specimen TCGA-D5-6539-01A from TCGA case TCGA-D5-6539, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; Age at diagnosis: 45.7 years (16,703 days).
Specimen TCGA-D5-6539-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.0dba2b5a-4e09-4d37-8c5a-50d8331134a8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-6539-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cd8b0f40-a39c-475b-9073-0a8f9f76577a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 181; copy number 2: 13,107; copy number 3: 29,402; copy number 4: 10,690; copy number 5: 4,041; copy number 6: 1,621; copy number 7: 638; copy number 8: 26; copy number 9: 56; copy number 15: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-6539-01A-11D-1717-01): tumor purity 0.23, ploidy 3.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 778 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:134,897,874–161,274,061, 444 genes, copy number 7–9 (broad region; genes not listed).
- chr6:161,353,679–161,446,016, 2 genes, copy number 8: AL132982.1, AL138716.1.
- chr12:990,509–8,055,517, 236 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr16:48,244,300–52,099,120, 96 genes, copy number 9–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 181. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
